Somatic mutation profile of tumor specimen TCGA-B8-A54H-01A (aliquot TCGA-B8-A54H-01A-11D-A33K-10) from TCGA case TCGA-B8-A54H, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 69.1 years (25,243 days).
Specimen TCGA-B8-A54H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f2bd9c6-535e-4e2e-8c6a-279d60faddd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-A54H-10A (Blood Derived Normal), aliquot TCGA-B8-A54H-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6dfd4e89-40ef-4ad8-8f4a-d6cae75d8e09

The open-access MAF lists 74 somatic variants for this specimen: 63 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 50, Silent 11, Frame Shift Del 10, Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs5030822, CM003061, CM941386, CM961439, COSV56544319, COSV56547906, COSV56565675; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASB8 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV56659070; called by muse, mutect2
- CAMTA2 | c.1730T>C p.L577P | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100772636; called by muse, mutect2, varscan2
- CDH18 | c.506C>G p.P169R | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56941899, COSV99935521; called by muse, mutect2
- CEP104 | c.1058C>G p.S353C | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100986629; called by muse, mutect2, varscan2
- CHCHD5 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV100260860; called by muse, mutect2, varscan2
- COL11A2 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.92); catalogued as rs1398299612; called by muse, mutect2
- CTNNA3 | c.958A>G p.T320A | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1263985923, COSV101049859; called by muse, mutect2, varscan2
- DPAGT1 | c.1210C>G p.L404V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV99598031; called by muse, mutect2, varscan2
- ECI2 | c.206A>G p.Y69C (on ENST00000380118 / NM_206836.3; = p.Y39C on NM_006117.2) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs373093644; called by muse, mutect2, varscan2
- ENOX1 | c.987G>T p.E329D | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV99816179; called by muse, mutect2, varscan2
- ERBB4 | c.674A>T p.Y225F | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as COSV99624907; called by muse, mutect2, varscan2
- FCRL3 | c.836G>C p.R279P | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV100943287, COSV63842670; called by muse, mutect2, varscan2
- GUCY2F | c.2196T>G p.D732E | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99485095; called by muse, mutect2, varscan2
- IFT81 | c.25A>G p.M9V | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375743897; called by muse, mutect2, varscan2
- ITGA4 | c.1242C>A p.F414L | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.26); catalogued as COSV52000458, COSV99276415; called by muse, mutect2, varscan2
- ITPR2 | c.6504A>G p.I2168M | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV101190010; called by muse, mutect2, varscan2
- KRT6C | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99360003; called by muse, mutect2, varscan2
- KRTAP5-2 | c.320del p.G107Afs*85 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | catalogued as rs1432537257; called by mutect2, varscan2
- LAMB4 | c.5218G>A p.D1740N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV99224263; called by muse, mutect2, varscan2
- LAMB4 | c.3473G>A p.C1158Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282774224, COSV52712905; called by muse, mutect2, varscan2
- LEMD3 | c.1645A>C p.S549R | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100384365; called by muse, mutect2, varscan2
- MDGA1 | c.2506T>G p.F836V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99776989; called by muse, mutect2, varscan2
- MED14 | c.1990C>A p.L664M | Missense Mutation (SNP) | VAF 73/276 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100247501; called by muse, mutect2, varscan2
- MMD | c.558A>C p.L186F | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV100017869; called by muse, mutect2, varscan2
- MMP9 | c.1199C>A p.A400E | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100812407, COSV100812414; called by muse, mutect2, varscan2
- MPP4 | c.584A>C p.Y195S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV100206952; called by muse, mutect2, varscan2
- NAT2 | c.11A>T p.E4V | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as COSV99674094; called by muse, mutect2, varscan2
- OR1L6 | c.728T>A p.V243D (on ENST00000373684; = p.V207D on NM_001004453.2) | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100490910; called by muse, mutect2, varscan2
- OR5M10 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.341); catalogued as COSV101595895; called by muse, mutect2
- OR6C2 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as COSV100498710; called by muse, mutect2, varscan2
- OSBP2 | c.2656G>T p.D886Y | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100213255; called by muse, mutect2, varscan2
- OSMR | c.2417C>A p.A806D | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV99953225; called by muse, mutect2, varscan2
- PCDH15 | c.4516G>C p.D1506H (on ENST00000644397 / NM_001354429.2; = p.L1466F on NM_001142770.3) | Missense Mutation (SNP) | VAF 17/263 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV64709194; called by muse, mutect2
- PDZD8 | c.2227T>A p.C743S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100559533; called by muse, mutect2, varscan2
- PNPLA3 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs868803123, COSV99337150; called by muse, mutect2, varscan2
- RNF14 | c.821C>A p.A274D | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100641236; called by muse, mutect2, varscan2
- RNF214 | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs1488315045, COSV100326738; called by muse, mutect2, varscan2
- SLC30A6 | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV99249727; called by muse, mutect2, varscan2
- SLCO1B3 | c.425G>T p.C142F | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53934723; called by muse, mutect2, varscan2
- SMARCA4 | c.3564C>G p.D1188E | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100758605, COSV60803444; called by muse, mutect2
- SMARCC2 | c.1826T>G p.L609R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99911407; called by muse, mutect2, varscan2
- SMARCC2 | c.1311-1G>C p.X437_splice | Splice Site (SNP) | VAF 14/63 reads (22%) | catalogued as COSV99911412; called by muse, mutect2, varscan2
- STK4 | c.1090C>G p.Q364E | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV100860208; called by muse, mutect2, varscan2
- TCP11L1 | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100178164; called by muse, mutect2, varscan2
- TGM2 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV100821648; called by muse, mutect2, varscan2
- TMEM63C | c.2273C>G p.S758C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as COSV100029465; called by muse, mutect2, varscan2
- ZBTB48 | c.1769A>C p.Q590P | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100887254; called by muse, mutect2, varscan2
- ZMIZ1 | c.59A>G p.Q20R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV100566166; called by muse, mutect2, varscan2
- ZNF318 | c.4230T>A p.F1410L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100546229; called by muse, mutect2, varscan2
- ZNF598 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs759638133, COSV101461968; called by mutect2, varscan2
- ZNF701 | c.1104A>T p.E368D (on ENST00000301093; = p.E302D on NM_018260.3) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV99990852; called by muse, mutect2, varscan2
- AKAP11 | c.5128del p.I1710* | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- CHTF18 | c.2759_2760del p.V920Gfs*59 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by pindel, varscan2
- CSPP1 | c.3327dup p.G1110Wfs*5 (on ENST00000676605; = p.G1069Wfs*5 on NM_024790.6) | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- HNRNPC | c.771dup p.D258Rfs*2 (on ENST00000420743; = p.D245Rfs*2 on NM_004500.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- NDUFA9 | c.634_637del p.R212Sfs*31 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- OAT | c.207_210del p.L70Gfs*3 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | called by mutect2, pindel, varscan2
- PCNX3 | c.2060del p.P687Lfs*2 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- PDE10A | c.428del p.K143Rfs*31 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- PTPRN | c.1632_1642delinsA p.T545Kfs*107 | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | called by pindel, varscan2*
- SBNO1 | c.491del p.N164Mfs*3 (on ENST00000420886; = p.N163Mfs*3 on NM_018183.5) | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by mutect2, pindel, varscan2
- TET2 | c.934_935del p.N312Yfs*18 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel, varscan2
- ARHGEF7 | c.1680C>T p.C560= (on ENST00000375741 / NM_001113511.2; = p.C382= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as COSV99521600; called by muse, mutect2, varscan2
- DARS1 | c.1080C>T p.V360= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99927595; called by mutect2, varscan2
- DNAH7 | c.10479C>A p.A3493= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100415493; called by muse, mutect2, varscan2
- HMCES | c.333T>G p.P111= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV101077228, COSV101077326; called by muse, mutect2, varscan2
- HS3ST3A1 | c.105C>T p.S35= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV99404337; called by muse, mutect2, varscan2
- LPCAT2 | c.159G>T p.A53= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV99527885; called by muse, mutect2, varscan2
- MECR | c.990A>G p.T330= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99747119; called by muse, mutect2, varscan2
- RPS6KC1 | c.1314T>A p.L438= | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as COSV100873918; called by muse, mutect2, varscan2
- SLC18B1 | c.849C>T p.S283= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs753165468, COSV99259136; called by muse, mutect2, varscan2
- SLC39A11 | c.246T>A p.A82= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV99723218; called by muse, mutect2, varscan2
- TENM1 | c.4176G>A p.E1392= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV100950210; called by muse, mutect2, varscan2
